Somatic mutation profile of tumor specimen TCGA-FE-A230-01A (aliquot TCGA-FE-A230-01A-11D-A14W-08) from TCGA case TCGA-FE-A230, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 30.1 years (10,999 days).
Specimen TCGA-FE-A230-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab1b6d70-1b18-4ba7-ab38-5fd1287ead0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A230-10A (Blood Derived Normal), aliquot TCGA-FE-A230-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb6cd7ef-2e65-48a3-a767-a003fcd54b86

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP83 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1224566169, COSV60410150; called by muse, mutect2, varscan2
- NLRP11 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs376879259; called by muse, mutect2, varscan2
- RYK | c.867dup p.N290Qfs*66 (on ENST00000620660 / NM_001005861.2; = p.N290Qfs*63 on NM_002958.4) | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- NRG1 | c.502+31395C>T | Intron (SNP) | VAF 18/58 reads (31%) | catalogued as rs199722954, COSV55154774; called by muse, mutect2, varscan2
